Somatic mutation profile of tumor specimen 0DHX43 from CCDI case PBBVAN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 8.4 years (3,075 days).
Specimen 0DHX43: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cec2d8e2-8e83-4aa5-8b6f-1a719c0cd887.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DHX1X (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/05f3ce2f-46f4-4afb-9bc2-e0c2fa7d3839

The open-access MAF lists 24 somatic variants for this specimen: 20 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Nonsense Mutation 3, Silent 2, Splice Region 1, Intron 1, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTL6A | c.491G>A p.R164H | Missense Mutation (SNP) | VAF 66/298 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs939181350, COSV66998984, COSV66999082; called by muse, mutect2, varscan2
- CHD8 | c.3544C>T p.R1182* (on ENST00000646647 / NM_001170629.2; = p.R903* on NM_020920.4) | Nonsense Mutation (SNP) | VAF 86/260 reads (33%) | catalogued as rs747319027; called by muse, mutect2, varscan2
- CIC | c.4535G>C p.R1512P | Missense Mutation (SNP) | VAF 29/477 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV50554672, COSV50623937; called by muse, mutect2
- EIF4E1B | c.474G>A p.T158= | Splice Region (SNP) | VAF 95/213 reads (45%) | catalogued as rs1316494602, COSV53781486; called by muse, mutect2, varscan2
- LMO7 | c.1640C>T p.P547L (on ENST00000357063; = p.P277L on NM_015842.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 159/361 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767126372; called by muse, mutect2, varscan2
- MAP3K8 | c.479C>T p.T160M | Missense Mutation (SNP) | VAF 161/362 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs754271777, COSV99552267; called by muse, mutect2, varscan2
- NCOR2 | c.5876del p.K1959Sfs*23 | Frame Shift Del (DEL) | VAF 52/104 reads (50%) | catalogued as COSV100656574; called by mutect2, varscan2
- PLD1 | c.1957G>A p.V653I | Missense Mutation (SNP) | VAF 165/335 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.251); catalogued as rs890068626; called by muse, mutect2, varscan2
- SLC35G3 | c.850G>A p.A284T | Missense Mutation (SNP) | VAF 46/411 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.011); catalogued as rs748027779, COSV52012021; called by muse, mutect2, varscan2
- SMARCA4 | c.2837C>A p.P946H | Missense Mutation (SNP) | VAF 152/332 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as COSV60798711; called by muse, mutect2, varscan2
- SRSF12 | c.404A>G p.D135G | Missense Mutation (SNP) | VAF 29/281 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs770995685; called by muse, varscan2
- CACNG4 | c.46G>T p.G16* | Nonsense Mutation (SNP) | VAF 32/388 reads (8%) | called by muse, mutect2
- CCDC32 | c.181G>A p.V61I | Missense Mutation (SNP) | VAF 142/291 reads (49%) | SIFT tolerated (0.39); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- DDX3X | c.617A>G p.Q206R (on ENST00000399959; = p.Q207R on NM_001356.5) | Missense Mutation (SNP) | VAF 159/164 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GNB2 | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 173/550 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- IVL | c.1450G>T p.E484* | Nonsense Mutation (SNP) | VAF 39/173 reads (23%) | called by muse, mutect2, varscan2
- PLA2G4E | c.1358C>A p.P453Q | Missense Mutation (SNP) | VAF 36/420 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.905); called by muse, mutect2
- PSG7 | c.725C>T p.P242L | Missense Mutation (SNP) | VAF 76/165 reads (46%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- RBM47 | c.856G>A p.V286M | Missense Mutation (SNP) | VAF 202/458 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- UGT2B28 | c.1575G>T p.K525N | Missense Mutation (SNP) | VAF 208/485 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- DHRSX | c.114C>T p.F38= | Silent (SNP) | VAF 116/246 reads (47%) | catalogued as rs1368716583, COSV100585240; called by muse, mutect2, varscan2
- WDR59 | c.1473T>G p.L491= | Silent (SNP) | VAF 117/326 reads (36%) | catalogued as rs1487158267; called by muse, mutect2, varscan2
- KRT2 | c.*30C>A | 3'UTR (SNP) | VAF 116/273 reads (42%) | catalogued as COSV100548410; called by muse, mutect2, varscan2
- MTSS1 | c.1036-29T>C | Intron (SNP) | VAF 18/40 reads (45%) | catalogued as rs780298777; called by muse, mutect2
